Somatic mutation profile of tumor specimen TCGA-EE-A3JI-06A (aliquot TCGA-EE-A3JI-06A-11D-A21A-08) from TCGA case TCGA-EE-A3JI, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.4 years (21,317 days).
Specimen TCGA-EE-A3JI-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38e49b76-f9e5-4175-89d4-8cde5198b676.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3JI-10A (Blood Derived Normal), aliquot TCGA-EE-A3JI-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2ccaf2c-321a-480e-aa77-430b753d6dcd

The open-access MAF lists 1,391 somatic variants for this specimen: 930 protein-altering or splice-affecting, 425 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 780, Silent 425, Nonsense Mutation 62, Frame Shift Del 61, Intron 18, Splice Site 10, Splice Region 9, RNA 8, In Frame Del 6, 5'Flank 4, 3'Flank 3, 3'UTR 3.

Variants (750 of 1,391; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852267, CM940735, COSV54381197; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GBA | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as rs121908309, CM940811, CX165705, COSV59169115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 212/354 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- OCA2 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868238523, COSV62337400, COSV62339851, COSV62344458; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PSG4 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 202/437 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV54932991; called by muse, mutect2, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 62/272 reads (23%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV59389041; called by muse, mutect2, varscan2
- AADACL3 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60199627; called by muse, mutect2, varscan2
- AADAT | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV61787530; called by muse, mutect2, varscan2
- ABCA10 | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52225519; called by muse, mutect2, varscan2
- ABCA13 | c.4819A>G p.S1607G | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV70033779; called by muse, mutect2, varscan2
- ABCA7 | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54032662; called by muse, mutect2, varscan2
- ABCB1 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55955494; called by muse, varscan2
- ABCC8 | c.3592C>T p.P1198S | Missense Mutation (SNP) | VAF 150/350 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56853203; called by muse, mutect2, varscan2
- ACAN | c.7406C>T p.P2469L (on ENST00000560601 / NM_001369268.1; = p.P2393L on NM_001135.3) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61363726; called by muse, mutect2, varscan2
- ACOT6 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867873268, COSV66968794; called by muse, mutect2, varscan2
- ACSM1 | c.120G>A p.W40* | Nonsense Mutation (SNP) | VAF 114/132 reads (86%) | catalogued as COSV54637523; called by muse, mutect2, varscan2
- ACTL9 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1205644681, COSV61006433; called by muse, mutect2, varscan2
- ACTN4 | c.1560_1561del p.K521Afs*43 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | catalogued as rs1274615294; called by pindel, varscan2
- ACTRT2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV65759722; called by muse, mutect2, varscan2
- ADAM21 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs775142915, COSV50791693; called by muse, mutect2, varscan2
- ADAMTSL1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 88/106 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52818812; called by muse, mutect2, varscan2
- ADCY10 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 83/192 reads (43%) | catalogued as COSV63242261; called by muse, mutect2, varscan2
- ADCY2 | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV57882580; called by muse, mutect2, varscan2
- ADD2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs1327135861, COSV100036769, COSV52464540; called by muse, mutect2, varscan2
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ADGRG4 | c.5830G>A p.G1944R | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV54957310, COSV54960650; called by muse, mutect2, varscan2
- ADGRV1 | c.9461C>T p.S3154F | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV67989183; called by muse, mutect2, varscan2
- ADGRV1 | c.11584G>A p.D3862N | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV67989186; called by muse, mutect2, varscan2
- AFP | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs747300521; called by muse, mutect2, varscan2
- AGXT2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51484632; called by muse, mutect2, varscan2
- AHNAK2 | c.7342A>G p.S2448G | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as COSV60920711; called by muse, mutect2
- AKR1B10 | c.413T>C p.F138S | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV62055918; called by muse, mutect2, varscan2
- AL645922.1 | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs749815658, COSV64888139; called by muse, mutect2, varscan2
- ALB | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV55739633; called by muse, mutect2, varscan2
- ALOXE3 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV58554918; called by muse, mutect2, varscan2
- ALPK1 | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1325424017, COSV51587473; called by muse, mutect2, varscan2
- AMER3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1200629352, COSV58465055; called by muse, mutect2, varscan2
- ANK1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 264/489 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs772202187, COSV55874800, COSV55892808; called by muse, mutect2, varscan2
- ANK3 | c.3304G>A p.E1102K (on ENST00000280772 / NM_001320874.2; = p.E236K on NM_001149.3) | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs376941205; called by muse, mutect2, varscan2
- ANK3 | c.2350C>T p.Q784* | Nonsense Mutation (SNP) | VAF 38/71 reads (54%) | catalogued as COSV55066537; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3824T>C p.V1275A | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51851860; called by muse, mutect2, varscan2
- ANKRD39 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV66813227; called by muse, mutect2, varscan2
- ANO5 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61083785, COSV61087223; called by muse, mutect2, varscan2
- AP4E1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV55918236; called by muse, mutect2, varscan2
- APC | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as CD106394, COSV57338942, COSV57357213; called by muse, mutect2, varscan2
- APLNR | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746406904; called by muse, mutect2, varscan2
- APOO | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV64870847; called by muse, mutect2, varscan2
- ARHGAP15 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs374653128; called by muse, mutect2, varscan2
- ARHGAP21 | c.4925C>T p.P1642L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV57607886; called by muse, mutect2, varscan2
- ARHGEF10 | c.963G>C p.K321N (on ENST00000398564; = p.K296N on NM_014629.4) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs1390318106, COSV50658164; called by muse, mutect2, varscan2
- ARHGEF40 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs763922926; called by muse, mutect2, varscan2
- ARHGEF40 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV53881787; called by muse, mutect2, varscan2
- ARHGEF6 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339750537, COSV51692969; called by muse, mutect2, varscan2
- ARHGEF7 | c.2579C>T p.T860I (on ENST00000646102 / NM_001354046.1; = p.T644I on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54546174; called by muse, mutect2, varscan2
- ARMC2 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1480322734, COSV64551974; called by muse, mutect2, varscan2
- ARMC4 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs868584068, COSV53466447; called by muse, mutect2, varscan2
- ARMS2 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.446); catalogued as COSV73307015; called by muse, mutect2
- ART5 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV51703850; called by muse, mutect2, varscan2
- ASTN1 | c.3375G>A p.W1125* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV62492952, COSV62499991; called by muse, mutect2, varscan2
- ATAD2 | c.4003-1G>A p.X1335_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54883203; called by muse, mutect2
- ATP10D | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV56709539; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 62/194 reads (32%) | catalogued as COSV59475313, COSV59477512; called by muse, mutect2, varscan2
- ATP6V0D2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV53415952; called by muse, mutect2, varscan2
- ATRX | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 79/94 reads (84%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.051); catalogued as COSV64879168; called by muse, mutect2, varscan2
- AVPR1B | c.1114C>T p.L372F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs782638808; called by muse, mutect2
- AXDND1 | c.1136A>C p.Y379S | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV62644690, COSV62645084; called by muse, mutect2, varscan2
- B4GALNT4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57324290; called by muse, mutect2, varscan2
- B4GALT4 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 63/107 reads (59%) | catalogued as COSV63295569, COSV63296093; called by muse, mutect2, varscan2
- BAHCC1 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57028943; called by muse, mutect2, varscan2
- BARD1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV53613702; called by muse, mutect2, varscan2
- BCLAF1 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.953); catalogued as COSV62143648; called by muse, mutect2, varscan2
- BEST2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1162832309, COSV50369298; called by muse, mutect2, varscan2
- BMPER | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 102/176 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51823958; called by muse, mutect2, varscan2
- BPGM | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV61324065, COSV61325139; called by muse, mutect2, varscan2
- BRCA2 | c.5375C>T p.S1792F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV66456901; called by muse, mutect2, varscan2
- BRPF3 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60208272; called by muse, mutect2, varscan2
- BRWD3 | c.3733C>T p.Q1245* | Nonsense Mutation (SNP) | VAF 11/11 reads (100%) | catalogued as COSV64750398; called by muse, mutect2, varscan2
- BUD31 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV56117532; called by muse, mutect2, varscan2
- C11orf65 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV67597882; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2, varscan2
- C4A | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs377362766, COSV101418296; called by muse, mutect2, varscan2
- C4B | c.3556G>A p.G1186R | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs761379471, COSV70313493; called by muse, mutect2, varscan2
- C6orf118 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764527923, COSV57816502; called by muse, mutect2, varscan2
- CABP5 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV53153181, COSV99506372; called by muse, mutect2, varscan2
- CACNA1A | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.075); catalogued as rs887308405, COSV64202761; called by muse, mutect2, varscan2
- CACNA1D | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55454196; called by muse, mutect2, varscan2
- CACNA1E | c.5956C>T p.P1986S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV62393695; called by muse, mutect2, varscan2
- CACNA1E | c.6254G>A p.R2085Q (on ENST00000367573 / NM_001205293.3; = p.R2042Q on NM_000721.4) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV62403523; called by muse, mutect2, varscan2
- CACNA1F | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59905352; called by muse, mutect2, varscan2
- CACNA2D2 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV56565596; called by muse, mutect2, varscan2
- CADM2 | c.1232C>T p.P411L (on ENST00000407528 / NM_001167674.2; = p.P413L on NM_153184.4) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67386258; called by muse, mutect2, varscan2
- CAMTA2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 170/279 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs764869219, COSV61835910; called by muse, mutect2, varscan2
- CAND1 | c.2153C>T p.T718I | Missense Mutation (SNP) | VAF 66/578 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV73389683; called by muse, mutect2, varscan2
- CAPN15 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.058); catalogued as rs1467477681; called by muse, mutect2, varscan2
- CAPN15 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV54834307; called by muse, mutect2, varscan2
- CASZ1 | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs903417536, COSV59738093; called by muse, mutect2, varscan2
- CAVIN1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 207/429 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1338573396, COSV63811902; called by muse, mutect2, varscan2
- CCDC68 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61604050; called by muse, mutect2
- CCDC73 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58800849; called by muse, mutect2, varscan2
- CCDC88B | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1457158687, COSV57266885; called by muse, mutect2, varscan2
- CD163L1 | c.2866G>A p.G956R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV58019242; called by muse, mutect2, varscan2
- CD93 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55665126, COSV55666493; called by muse, mutect2, varscan2
- CDCA4 | c.465_466del p.G156Kfs*7 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | catalogued as rs1433343412; called by pindel, varscan2
- CDH12 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 95/212 reads (45%) | catalogued as rs773228403, COSV66388324, COSV66420863; called by muse, mutect2, varscan2
- CDH13 | c.1090A>C p.T364P | Missense Mutation (SNP) | VAF 94/115 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51838654; called by muse, mutect2, varscan2
- CDH15 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 85/108 reads (79%) | catalogued as COSV57025494; called by muse, mutect2, varscan2
- CDH6 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV54073351; called by muse, mutect2, varscan2
- CDH9 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50250776, COSV50334530; called by muse, mutect2, varscan2
- CDHR1 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60564062; called by muse, mutect2, varscan2
- CDHR2 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56141266; called by muse, mutect2, varscan2
- CEACAM16 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs763317239, COSV69187372; called by muse, mutect2
- CELSR3 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369332360; called by muse, mutect2, varscan2
- CENPL | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs754472381, COSV61892419; called by muse, mutect2, varscan2
- CEP152 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs762785569; called by muse, mutect2, varscan2
- CFAP299 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866257430, COSV63880963; called by muse, mutect2, varscan2
- CFAP46 | c.7625C>T p.S2542F | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.347); catalogued as COSV54154688; called by muse, mutect2, varscan2
- CFAP54 | c.6475-1G>A p.X2159_splice | Splice Site (SNP) | VAF 16/20 reads (80%) | catalogued as COSV61573115; called by muse, mutect2, varscan2
- CFAP91 | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 35/66 reads (53%) | catalogued as COSV56342262; called by muse, mutect2, varscan2
- CFAP92 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV54046765; called by muse, mutect2, varscan2
- CFHR5 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV56823922; called by muse, mutect2, varscan2
- CFHR5 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs199531514, COSV56822278; called by muse, mutect2, varscan2
- CHAMP1 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV63521669; called by muse, mutect2, varscan2
- CHAMP1 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs574134204, COSV63522676; called by muse, mutect2, varscan2
- CHD5 | c.2938G>A p.V980I | Missense Mutation (SNP) | VAF 388/619 reads (63%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV52418939; called by muse, mutect2, varscan2
- CHD7 | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71112440; called by muse, mutect2, varscan2
- CHRNA2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs968676056, COSV53558418; called by muse, mutect2, varscan2
- CHRNA5 | c.1254A>T p.E418D | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV55139231; called by muse, mutect2, varscan2
- CHST3 | c.72C>A p.Y24* | Nonsense Mutation (SNP) | VAF 48/150 reads (32%) | catalogued as COSV100910362, COSV64151224; called by muse, mutect2, varscan2
- CIB3 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 130/338 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV54166886; called by muse, mutect2
- CLEC4C | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV63582634; called by muse, mutect2, varscan2
- CLIC6 | c.1454G>A p.G485E (on ENST00000360731 / NM_001317009.2; = p.G467E on NM_053277.3) | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62447578; called by muse, mutect2, varscan2
- CLSTN3 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1390323681; called by muse, varscan2
- CMPK2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391435644, COSV56775274; called by muse, mutect2, varscan2
- CNDP2 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV60840537; called by muse, mutect2, varscan2
- CNIH3 | c.21del p.F8Sfs*21 | Frame Shift Del (DEL) | VAF 299/1050 reads (28%) | catalogued as COSV55273300, COSV55279509; called by mutect2, pindel, varscan2
- CNKSR3 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as rs760907490; called by muse, mutect2, varscan2
- CNPY1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.578); catalogued as rs749662605, COSV58786461; called by muse, mutect2, varscan2
- CNTNAP1 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 124/265 reads (47%) | catalogued as rs144659252, COSV99226269; called by muse, mutect2, varscan2
- CNTNAP2 | c.2385G>A p.R795= | Splice Region (SNP) | VAF 46/150 reads (31%) | catalogued as COSV62151746; called by muse, mutect2, varscan2
- CNTNAP5 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV70494464; called by muse, mutect2, varscan2
- CNTRL | c.3482C>T p.A1161V | Missense Mutation (SNP) | VAF 55/60 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53049426; called by muse, mutect2, varscan2
- COG2 | c.792T>A p.F264L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64187420; called by muse, mutect2, varscan2
- COL12A1 | c.8372C>T p.P2791L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59399906; called by muse, mutect2, varscan2
- COL17A1 | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62227862; called by muse, mutect2, varscan2
- COL1A1 | c.3380G>C p.G1127A | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56806915; called by muse, mutect2, varscan2
- COL4A1 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 81/335 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65427963; called by muse, mutect2, varscan2
- COL4A2 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64630240; called by muse, mutect2
- COL5A1 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 70/84 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65671274, COSV65672686; called by muse, mutect2, varscan2
- COL5A1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV65671281; called by muse, mutect2, varscan2
- COL5A3 | c.3005C>T p.P1002L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs1231555242, COSV53413782; called by muse, mutect2, varscan2
- COL6A3 | c.5641C>T p.R1881C | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs772269570, COSV55096423; called by muse, mutect2, varscan2
- COL6A3 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs144651558; called by muse, mutect2, varscan2
- COL6A6 | c.3509G>A p.R1170K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs753977264, COSV62029614; called by muse, mutect2, varscan2
- COMMD9 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 66/157 reads (42%) | catalogued as COSV54672738; called by muse, mutect2, varscan2
- CORIN | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as COSV56694321; called by muse, mutect2, varscan2
- CORO1C | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54597281; called by muse, mutect2, varscan2
- CPAMD8 | c.3512G>A p.G1171E (on ENST00000651564; = p.G1124E on NM_015692.5) | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71596821; called by muse, mutect2, varscan2
- CPB2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.46); catalogued as COSV51675612; called by muse, mutect2, varscan2
- CPZ | c.1147G>A p.D383N (on ENST00000360986 / NM_001014447.3; = p.D372N on NM_003652.3) | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs748182777, COSV59924014; called by muse, mutect2, varscan2
- CR1 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0.036); catalogued as rs1215770381, COSV100887666; called by muse, mutect2, varscan2
- CR2 | c.1544G>A p.W515* | Nonsense Mutation (SNP) | VAF 128/220 reads (58%) | catalogued as COSV65508475; called by muse, mutect2, varscan2
- CRACD | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV51725232; called by muse, varscan2
- CRYBA4 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1379946401, COSV61322341; called by muse, mutect2, varscan2
- CRYBG1 | c.6302-1G>A p.X2101_splice | Splice Site (SNP) | VAF 78/140 reads (56%) | catalogued as COSV64805734; called by muse, mutect2, varscan2
- CRYGB | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV53680520; called by muse, mutect2, varscan2
- CSMD1 | c.3181C>T p.H1061Y (on ENST00000520002; = p.H1060Y on NM_033225.6) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV59325986; called by muse, mutect2, varscan2
- CSMD2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53922489; called by muse, mutect2, varscan2
- CSPG4 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV57897675; called by muse, mutect2, varscan2
- CTAGE1 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV66943892, COSV66945275; called by muse, mutect2, varscan2
- CTAGE15 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.876); catalogued as COSV69482076; called by muse, mutect2, varscan2
- CTC1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 134/228 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV59854007; called by muse, mutect2, varscan2
- CTNND2 | c.2195G>A p.R732K | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.829); catalogued as COSV58888359, COSV58903207; called by muse, mutect2, varscan2
- CWH43 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV56937816, COSV56940633; called by muse, mutect2, varscan2
- CX3CL1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1347011692, COSV50055693; called by muse, mutect2, varscan2
- CYB5R4 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.658); catalogued as COSV63751286; called by muse, mutect2, varscan2
- CYP11A1 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51433051; called by muse, mutect2, varscan2
- CYP2C8 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1440353583, COSV64877869; called by muse, mutect2, varscan2
- CYP8B1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as COSV60226913; called by muse, mutect2, varscan2
- CYS1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1283433619, COSV59940889; called by muse, mutect2, varscan2
- DAB1 | c.1660G>T p.E554* (on ENST00000371231; = p.E521* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 75/138 reads (54%) | catalogued as COSV64694519; called by muse, mutect2, varscan2
- DAG1 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 136/298 reads (46%) | catalogued as rs1445953917, COSV58185401; called by muse, mutect2, varscan2
- DALRD3 | c.1065C>T p.D355= (on ENST00000341949 / NM_001009996.3; = p.D188= on NM_018114.5) | Splice Region (SNP) | VAF 49/110 reads (45%) | catalogued as COSV58245703; called by muse, mutect2, varscan2
- DBH | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 51/66 reads (77%) | catalogued as COSV55041607; called by muse, mutect2, varscan2
- DDX24 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100427896; called by muse, mutect2, varscan2
- DDX42 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV63790589; called by muse, mutect2, varscan2
- DEAF1 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1166736149, COSV58607924; called by muse, mutect2, varscan2
- DENND6A | c.1676T>G p.L559W | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60769246; called by muse, mutect2
- DHX37 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 83/259 reads (32%) | catalogued as COSV58136449; called by muse, mutect2, varscan2
- DIP2C | c.1432A>G p.K478E | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55165754; called by muse, mutect2, varscan2
- DLG2 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV54625070, COSV99719151; called by muse, mutect2, varscan2
- DMBT1 | c.6463G>A p.G2155R (on ENST00000338354 / NM_001377530.1; = p.G1398R on NM_004406.3) | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.621); catalogued as rs541947593, COSV57549935; called by muse, mutect2, varscan2
- DNAH9 | c.4605G>T p.Q1535H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52358759; called by muse, mutect2, varscan2
- DNAI2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs757238033, COSV56760101; called by muse, mutect2, varscan2
- DOCK3 | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs868494898, COSV56532166; called by muse, mutect2, varscan2
- DONSON | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs778020919, COSV51678405; called by muse, mutect2, varscan2
- DPP8 | c.269A>G p.D90G (on ENST00000341861 / NM_001320875.2; = p.D74G on NM_017743.6) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.333); catalogued as COSV55680427; called by muse, mutect2, varscan2
- DPPA2 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs368412698; called by muse, mutect2, varscan2
- DSCAM | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV68645845; called by muse, mutect2, varscan2
- DSG1 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57136989; called by muse, mutect2, varscan2
- DUS4L | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs184033937, COSV50053105; called by muse, mutect2, varscan2
- DYNC1I2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV55527383; called by muse, mutect2, varscan2
- DYRK3 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV65606806; called by muse, mutect2, varscan2
- EBPL | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374216796; called by muse, mutect2, varscan2
- ECD | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1399485010, COSV65900435; called by muse, mutect2, varscan2
- ECE1 | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894874834, COSV51666667, COSV99942556; called by muse, mutect2, varscan2
- ECT2L | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 93/342 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62885643; called by muse, mutect2, varscan2
- EDC3 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs773815619, COSV59340887; called by muse, mutect2, varscan2
- EFCAB13 | c.394A>C p.K132Q | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV58950062; called by muse, mutect2, varscan2
- EGR1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 90/108 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53520275; called by muse, mutect2, varscan2
- EI24 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV54020038, COSV54020572; called by muse, mutect2, varscan2
- ELAPOR2 | c.3077C>T p.S1026F (on ENST00000450689 / NM_001142749.3; = p.S859F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs747623809, COSV51888492; called by muse, mutect2, varscan2
- ELAPOR2 | c.2521C>T p.P841S (on ENST00000450689 / NM_001142749.3; = p.P674S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51884556; called by muse, mutect2, varscan2
- ELFN2 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 130/216 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV68745219; called by muse, mutect2, varscan2
- ELL2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52983648; called by muse, varscan2
- ELMOD3 | c.130-1G>A p.X44_splice | Splice Site (SNP) | VAF 21/52 reads (40%) | catalogued as rs1558694631, COSV59773677; called by muse, mutect2, varscan2
- EMB | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57483063; called by muse, mutect2, varscan2
- EMILIN2 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54425135; called by muse, mutect2, varscan2
- EML4 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV59295742, COSV59300836; called by muse, mutect2, varscan2
- EPHA6 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1483105928, COSV67569289; called by muse, mutect2, varscan2
- EPHA8 | c.2832G>A p.M944I | Missense Mutation (SNP) | VAF 88/353 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV51275410; called by muse, mutect2, varscan2
- EPHX1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV55302145; called by muse, mutect2, varscan2
- ERCC1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV50004607; called by muse, mutect2, varscan2
- ERN1 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV70503096; called by muse, mutect2
- ETAA1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as COSV55472623; called by muse, mutect2, varscan2
- EXOC6B | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs760406183, COSV55561407, COSV99725752; called by muse, mutect2, varscan2
- EXPH5 | c.5345C>T p.S1782F | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV56204541; called by muse, mutect2, varscan2
- EYA4 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62055916; called by muse, mutect2, varscan2
- FAM117B | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.116); catalogued as COSV57420233; called by muse, mutect2, varscan2
- FAM124B | c.321T>A p.C107* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as COSV66272749; called by muse, mutect2, varscan2
- FAM135B | c.3223G>A p.G1075R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52736564; called by muse, mutect2, varscan2
- FAM161B | c.874C>T p.L292F (on ENST00000651776; = p.L229F on NM_152445.3) | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54103114; called by muse, mutect2, varscan2
- FAM170A | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 92/108 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58925972; called by muse, mutect2, varscan2
- FAM184A | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 90/164 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58855992; called by muse, mutect2, varscan2
- FASTKD5 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53907166; called by muse, mutect2, varscan2
- FAT3 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53136242; called by muse, mutect2, varscan2
- FBLN1 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV53049875; called by muse, mutect2, varscan2
- FBLN5 | c.17+2T>A p.X6_splice | Splice Site (SNP) | VAF 36/43 reads (84%) | catalogued as COSV99969665; called by muse, mutect2, varscan2
- FBXO24 | c.983C>T p.T328I (on ENST00000241071 / NM_033506.3; = p.T366I on NM_012172.5) | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV53827421; called by muse, mutect2, varscan2
- FCGBP | c.10424G>A p.G3475D | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360715190; called by muse, mutect2, varscan2
- FCGBP | c.6820G>A p.G2274S | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1315956102; called by muse, varscan2
- FCGBP | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 206/440 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs889142936; called by muse, mutect2, varscan2
- FCGBP | c.1037A>C p.Y346S | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs751803397; called by muse, mutect2, varscan2
- FCGR1A | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); catalogued as COSV64985719; called by muse, mutect2, varscan2
- FDXR | c.970G>A p.A324T (on ENST00000293195 / NM_024417.5; = p.A330T on NM_004110.6) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV53115056; called by muse, mutect2, varscan2
- FECH | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473080671, COSV50491502; called by muse, mutect2, varscan2
- FHL5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV58735980; called by muse, mutect2, varscan2
- FILIP1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52734336; called by muse, mutect2, varscan2
- FLG | c.8291G>A p.G2764E | Missense Mutation (SNP) | VAF 135/753 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1329246963, COSV64244041; called by muse, mutect2, varscan2
- FN3KRP | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as COSV53930233; called by muse, mutect2, varscan2
- FNDC11 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 157/372 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64443074; called by muse, mutect2, varscan2
- FREM1 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as COSV66526085; called by muse, mutect2, varscan2
- FSIP2 | c.18997G>A p.E6333K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.918); catalogued as rs867705713, COSV58080987; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- FXYD5 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV61569165; called by muse, mutect2, varscan2
- GABRA3 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1228855985, COSV64798895, COSV64800358; called by muse, mutect2, varscan2
- GABRG2 | c.385A>C p.N129H | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62719602; called by muse, mutect2, varscan2
- GADL1 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs1359116959, COSV56981332; called by muse, mutect2, varscan2
- GALK2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59102824; called by muse, mutect2, varscan2
- GALNT12 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV66663100; called by muse, mutect2, varscan2
- GALNT18 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766330240, COSV57158522; called by muse, mutect2, varscan2
- GALNT3 | c.452A>T p.N151I | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67062010; called by muse, mutect2, varscan2
- GATAD2B | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64084791; called by muse, mutect2, varscan2
- GCN1 | c.5650C>T p.R1884W | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403344149, COSV56110353; called by muse, mutect2, varscan2
- GK2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 130/244 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs149134428, COSV62626058, COSV62628077; called by muse, mutect2, varscan2
- GLMP | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.982); catalogued as rs770484969, COSV55296111; called by muse, mutect2, varscan2
- GNAT2 | c.540A>T p.K180N | Missense Mutation (SNP) | VAF 135/216 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63555108; called by muse, mutect2, varscan2
- GPLD1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV57758869; called by muse, mutect2, varscan2
- GPR119 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 66/71 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52275985, COSV99358606; called by muse, mutect2, varscan2
- GPR156 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59940981; called by muse, mutect2, varscan2
- GPR158 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1451450463, COSV66274647; called by muse, mutect2, varscan2
- GRAMD4 | c.933C>T p.N311= | Splice Region (SNP) | VAF 72/305 reads (24%) | catalogued as rs550170017, COSV63031094; called by muse, mutect2, varscan2
- GRHL1 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | catalogued as COSV61409148; called by muse, mutect2, varscan2
- GRID2 | c.735+1G>A p.X245_splice | Splice Site (SNP) | VAF 38/72 reads (53%) | catalogued as COSV56226000; called by muse, varscan2
- GRIK1 | c.780G>A p.L260= | Splice Region (SNP) | VAF 155/283 reads (55%) | catalogued as rs372042615; called by muse, mutect2, varscan2
- GRIN1 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100160854; called by muse, mutect2, varscan2
- GRIP2 | c.1265G>A p.R422Q (on ENST00000619221; = p.R325Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs111407877, COSV56122663; called by muse, mutect2, varscan2
- GRK7 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV53823812; called by muse, mutect2, varscan2
- GTF2B | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV65137326; called by muse, mutect2, varscan2
- H2AC1 | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV51237448, COSV51237689; called by muse, mutect2, varscan2
- HAS2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 70/108 reads (65%) | catalogued as COSV58265301; called by muse, mutect2, varscan2
- HAX1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs200890522; called by muse, mutect2, varscan2
- HBS1L | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.33); catalogued as rs562783458, COSV100892544; called by muse, mutect2, varscan2
- HCFC2 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 45/192 reads (23%) | catalogued as COSV57559058; called by muse, mutect2, varscan2
- HDGFL2 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100012447; called by muse, mutect2, varscan2
- HECW1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67833752; called by muse, mutect2, varscan2
- HECW2 | c.2051G>T p.C684F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV53648383, COSV53664917; called by muse, mutect2, varscan2
- HELB | c.3076G>T p.D1026Y | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.533); catalogued as COSV56074560; called by muse, mutect2, varscan2
- HIPK2 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV61229776; called by muse, mutect2, varscan2
- HK1 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53860776; called by muse, mutect2, varscan2
- HLA-DQA1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58238324, COSV58240182; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61255226; called by muse, mutect2, varscan2
- HOGA1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV65706534; called by muse, mutect2, varscan2
- HOOK3 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV56884370; called by muse, mutect2, varscan2
- HSH2D | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs767564094, COSV53738659; called by muse, mutect2, varscan2
- HTR5A | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55284728; called by muse, mutect2, varscan2
- HTT | c.4619C>T p.P1540L | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs749310222; called by muse, varscan2
- HTT | c.7688C>T p.S2563L | Missense Mutation (SNP) | VAF 155/311 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV61864920; called by muse, mutect2, varscan2
- HTT | c.9373C>T p.P3125S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61864925; called by muse, mutect2, varscan2
- HUWE1 | c.10900C>T p.L3634F | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs868989208, COSV53353059; called by muse, mutect2, varscan2
- HYDIN | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV66636817; called by muse, mutect2, varscan2
- IDH1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs555882127, COSV61620782; called by muse, mutect2, varscan2
- IFNL3 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 150/293 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.393); catalogued as COSV69830077; called by muse, mutect2, varscan2
- IFT22 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV59527463; called by muse, mutect2, varscan2
- IGDCC4 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 77/175 reads (44%) | catalogued as COSV61537915; called by muse, mutect2, varscan2
- IGSF21 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 85/304 reads (28%) | catalogued as rs867147194, COSV52137325; called by muse, mutect2, varscan2
- IGSF22 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 154/345 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV60035941; called by muse, mutect2, varscan2
- IL1RAPL2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV61143544, COSV61155825; called by muse, mutect2, varscan2
- IL31RA | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); catalogued as COSV51682840; called by muse, mutect2, varscan2
- IMPG1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as COSV64059372, COSV64060837; called by muse, mutect2, varscan2
- INTS5 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 109/229 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as rs1286029800, COSV57952318; called by muse, mutect2, varscan2
- INTU | c.1053_1054del p.C351* | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs779685404; called by pindel, varscan2
- ITGAL | c.2317G>T p.E773* | Nonsense Mutation (SNP) | VAF 184/224 reads (82%) | catalogued as COSV63321788, COSV63323049; called by muse, mutect2, varscan2
- ITLN1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58275835; called by muse, mutect2, varscan2
- IVNS1ABP | c.1142G>T p.C381F | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62251475; called by muse, mutect2, varscan2
- JAKMIP1 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369217731; called by muse, mutect2, varscan2
- KCNA7 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs762119570, COSV55503557; called by muse, mutect2, varscan2
- KCND3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV56183989; called by muse, mutect2, varscan2
- KCNF1 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | catalogued as rs1158819101, COSV54464321; called by muse, mutect2, varscan2
- KCNH7 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV59802693; called by muse, mutect2, varscan2
- KCNK2 | c.922G>A p.G308R (on ENST00000444842 / NM_001017425.3; = p.G293R on NM_014217.4) | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV67207551; called by muse, mutect2, varscan2
- KCNMB4 | c.110T>A p.F37Y | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV50692060; called by muse, mutect2
- KCNT2 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1309180693, COSV54064787; called by muse, mutect2, varscan2
- KDM1A | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.312); catalogued as COSV56502859; called by muse, mutect2, varscan2
- KDM2A | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV67082801; called by muse, mutect2, varscan2
- KDM3A | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57222790; called by muse, mutect2
- KEL | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.299); catalogued as COSV62336090; called by muse, mutect2, varscan2
- KIF1C | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1199087791; called by muse, mutect2, varscan2
- KIR2DL4 | c.248G>A p.G83E (on ENST00000396284; = p.G44E on NM_001080770.2) | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs764264574; called by muse, mutect2, varscan2
- KIRREL2 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201575059, COSV52874647; called by muse, mutect2, varscan2
- KL | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 59/140 reads (42%) | catalogued as rs1384221025, COSV66307765; called by muse, mutect2, varscan2
- KLHDC8A | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65678990; called by muse, mutect2, varscan2
- KLHL22 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1205647733, COSV61021670; called by muse, mutect2, varscan2
- KLK3 | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 118/259 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58100169, COSV58101347; called by muse, mutect2, varscan2
- KMT2B | c.1007G>T p.W336L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52892807; called by muse, mutect2, varscan2
- KNDC1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs777098922, COSV58840987; called by muse, mutect2, varscan2
- KPRP | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175728082, COSV64221236; called by muse, mutect2, varscan2
- KRT13 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755872173, COSV55839832; called by muse, varscan2
- KRT13 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1449924878, COSV55839099; called by muse, varscan2
- KSR1 | c.1161A>C p.E387D (on ENST00000644974 / NM_001367810.1; = p.E250D on NM_014238.2) | Missense Mutation (SNP) | VAF 187/315 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.249); catalogued as COSV52035113; called by muse, mutect2, varscan2
- L3MBTL1 | c.2357C>A p.T786K (on ENST00000418998 / NM_001377303.1; = p.T696K on NM_015478.7) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64228970; called by muse, mutect2, varscan2
- LANCL1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV52064453; called by muse, mutect2, varscan2
- LAPTM5 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV53853777; called by muse, mutect2, varscan2
- LARGE1 | c.2037G>A p.W679* | Nonsense Mutation (SNP) | VAF 46/179 reads (26%) | catalogued as COSV61665402; called by muse, mutect2, varscan2
- LARP4B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 89/115 reads (77%) | catalogued as COSV60221003; called by muse, mutect2, varscan2
- LARS2 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs771914374, COSV55529134; called by muse, mutect2, varscan2
- LCK | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60741351; called by muse, mutect2, varscan2
- LCT | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1157333495, COSV51552627; called by muse, mutect2, varscan2
- LHCGR | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54299317, COSV54299540; called by muse, mutect2, varscan2
- LIG3 | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52008920; called by muse, mutect2, varscan2
- LILRA2 | c.33C>T p.L11= | Splice Region (SNP) | VAF 71/433 reads (16%) | catalogued as rs759331053, COSV99252747; called by muse, mutect2, varscan2
- LLGL2 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1422808547, COSV51365380; called by muse, mutect2, varscan2
- LMOD2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71755717; called by muse, mutect2, varscan2
- LNX1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55788110, COSV99819860; called by muse, mutect2, varscan2
- LONP2 | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53523737; called by muse, mutect2, varscan2
- LPA | c.5896G>A p.E1966K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV60304735; called by muse, mutect2, varscan2
- LRAT | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV60477528; called by muse, mutect2, varscan2
- LRIG3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 99/127 reads (78%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs571495948, COSV57862213; called by muse, mutect2, varscan2
- LRRC20 | c.295C>G p.L99V (on ENST00000355790 / NM_207119.3; = p.L49V on NM_018239.4) | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV62938665; called by muse, mutect2, varscan2
- LRRIQ3 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV63046147; called by muse, mutect2, varscan2
- LRRIQ4 | c.1507A>G p.N503D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV61619593; called by muse, mutect2, varscan2
- LRTM1 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55554982; called by muse, mutect2, varscan2
- LSM10 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV59872467; called by muse, mutect2, varscan2
- LTBP2 | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV56210351; called by muse, mutect2
- MACF1 | c.6230C>T p.S2077F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as rs1173331485, COSV57129761; called by muse, mutect2, varscan2
- MAFG | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as rs1051803653, COSV60815721; called by muse, mutect2, varscan2
- MALT1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61935513; called by muse, mutect2, varscan2
- MAN2B2 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV53454689; called by muse, mutect2, varscan2
- MANF | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs1195052399, COSV56532174; called by muse, mutect2
- MAP3K14 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV59304197; called by muse, mutect2, varscan2
- MAP3K19 | c.3043G>A p.G1015S | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV59640389; called by muse, mutect2, varscan2
- MAST4 | c.7568C>T p.S2523F (on ENST00000403625 / NM_001164664.2; = p.S2334F on NM_015183.3) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as COSV55119927; called by muse, mutect2, varscan2
- MCHR2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs767801578, COSV56003223; called by muse, mutect2, varscan2
- MCPH1 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs780510014, COSV60915714; called by muse, mutect2, varscan2
- MDC1 | c.4937C>T p.S1646F | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV64525092; called by muse, mutect2, varscan2
- MDN1 | c.13730C>T p.A4577V | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV65524460; called by muse, mutect2, varscan2
- MINK1 | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV61791103; called by muse, mutect2, varscan2
- MLIP | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51426606; called by muse, mutect2, varscan2
- MMD | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 148/357 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs556969177, COSV50435363; called by muse, mutect2, varscan2
- MMEL1 | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 84/138 reads (61%) | catalogued as COSV56523048; called by muse, mutect2, varscan2
- MMP1 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV59510848; called by muse, mutect2, varscan2
- MMP13 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52824584; called by muse, mutect2, varscan2
- MMRN1 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.518); catalogued as rs748993757, COSV53339353; called by muse, mutect2, varscan2
- MORC1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV51713955; called by muse, mutect2, varscan2
- MROH2B | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as rs866382870, COSV68186134; called by muse, mutect2, varscan2
- MROH8 | c.1620G>A p.W540* | Nonsense Mutation (SNP) | VAF 37/69 reads (54%) | catalogued as rs1386327002; called by muse, mutect2, varscan2
- MSL1 | c.1102C>T p.P368S (on ENST00000398532 / NM_001365919.1; = p.P105S on NM_001012241.2) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1280260665, COSV59899452; called by muse, mutect2, varscan2
- MUC16 | c.42619C>T p.H14207Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.824); catalogued as COSV66689858; called by muse, mutect2, varscan2
- MUC16 | c.32147C>T p.P10716L | Missense Mutation (SNP) | VAF 253/548 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.069); catalogued as rs770271863, COSV67477145; called by muse, mutect2, varscan2
- MUC16 | c.29351C>T p.P9784L | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.451); catalogued as COSV67477151; called by muse, mutect2, varscan2
- MUC16 | c.26542G>A p.E8848K | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs758682809, COSV67446748, COSV67446844; called by muse, mutect2, varscan2
- MUC16 | c.23887C>T p.P7963S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV67440951; called by muse, mutect2, varscan2
- MUC16 | c.19538C>T p.S6513F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs1217887114, COSV67454232; called by muse, mutect2, varscan2
- MUC16 | c.9637G>A p.E3213K | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs865897685, COSV101197664, COSV67467593; called by muse, mutect2, varscan2
- MUC16 | c.8780C>T p.S2927F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs983814591, COSV67477166; called by muse, mutect2, varscan2
- MUC16 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs573506587, COSV67484109; called by muse, mutect2, varscan2
- MUC3A | c.7997G>A p.G2666E | Missense Mutation (SNP) | VAF 85/715 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.537); catalogued as rs762464654, COSV60211557; called by muse, mutect2, varscan2
- MYBBP1A | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 151/229 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV54599838; called by muse, mutect2, varscan2
- MYC | c.200C>T p.S67F (on ENST00000377970; = p.S82F on NM_002467.6) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV52375491; called by muse, varscan2
- MYH13 | c.4378T>C p.W1460R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV52834096; called by muse, mutect2, varscan2
- MYH2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55441809; called by muse, mutect2, varscan2
- MYH8 | c.4495G>A p.E1499K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs370499944; called by muse, mutect2
- MYO16 | c.3494A>T p.Q1165L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV62753546; called by muse, mutect2, varscan2
- MYO1E | c.127T>G p.Y43D | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55690316; called by muse, mutect2, varscan2
- NAALAD2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV58962941; called by muse, mutect2, varscan2
- NALCN | c.3479A>T p.N1160I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV51946824; called by muse, mutect2, varscan2
- NAPEPLD | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58522980; called by muse, mutect2, varscan2
- NARF | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV59112569; called by muse, mutect2, varscan2
- NAV3 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs1335504706, COSV57092270; called by muse, mutect2, varscan2
- NBPF1 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); catalogued as rs1448945030; called by mutect2, varscan2
- NCKAP5 | c.4420G>A p.E1474K | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1206719076, COSV58455946; called by muse, mutect2, varscan2
- NCOA6 | c.3188C>T p.P1063L | Missense Mutation (SNP) | VAF 196/459 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs752025910, COSV62861671; called by muse, mutect2, varscan2
- NDUFS3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 148/407 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV55455385; called by muse, mutect2, varscan2
- NDUFS4 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57020008; called by muse, mutect2, varscan2
- NEFH | c.1973_1978del p.E658_E659del | In Frame Del (DEL) | VAF 18/137 reads (13%) | catalogued as rs149571560; called by mutect2*, varscan2
- NEK9 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53132011; called by muse, mutect2, varscan2
- NEO1 | c.1705A>T p.I569F | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56074091; called by muse, mutect2
- NEXMIF | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV50048087, COSV50061670; called by muse, mutect2, varscan2
- NFIC | c.287T>G p.I96S | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV59413875; called by muse, mutect2, varscan2
- NFKB2 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384243168; called by muse, mutect2, varscan2
- NINL | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs760242811, COSV54004942; called by muse, mutect2, varscan2
- NISCH | c.4231C>T p.R1411C | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs753762136, COSV58739435; called by muse, mutect2, varscan2
- NKX2-1 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV61389306; called by muse, mutect2, varscan2
- NLRC3 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV57092839, COSV57095920; called by muse, mutect2, varscan2
- NLRP10 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1246431894, COSV60781007; called by muse, mutect2, varscan2
- NLRP11 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV64086493; called by muse, varscan2
- NLRP12 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 117/266 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.691); catalogued as COSV60744058, COSV60750037; called by muse, mutect2, varscan2
- NLRP6 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV56458391; called by muse, mutect2, varscan2
- NLRP8 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV52584870; called by muse, mutect2
- NLRP9 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs773348206, COSV60465119; called by muse, mutect2, varscan2
- NOL6 | c.2364+2T>C p.X788_splice | Splice Site (SNP) | VAF 71/82 reads (87%) | catalogued as COSV53043309; called by muse, mutect2, varscan2
- NPLOC4 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV58617243; called by muse, mutect2, varscan2
- NSD1 | c.7581G>A p.W2527* | Nonsense Mutation (SNP) | VAF 56/270 reads (21%) | catalogued as COSV61778909; called by muse, mutect2, varscan2
- NTPCR | c.328_329del p.C110Rfs*4 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | catalogued as rs772094652; called by pindel, varscan2
- NTRK2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52870039; called by muse, mutect2, varscan2
- NUMA1 | c.5873C>G p.T1958S | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV52621688; called by muse, mutect2, varscan2
- NUP155 | c.3598G>A p.E1200K (on ENST00000231498 / NM_153485.3; = p.E1141K on NM_004298.4) | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51526779; called by muse, mutect2, varscan2
- NUP210L | c.5573T>C p.F1858S | Missense Mutation (SNP) | VAF 98/181 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55151339; called by muse, mutect2, varscan2
- ODF1 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1452466150, COSV53433147; called by muse, mutect2, varscan2
- OGDHL | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs267602514, COSV65103428; called by muse, mutect2, varscan2
- OGFOD3 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 102/468 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57341811; called by muse, mutect2, varscan2
- OIT3 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV61825707, COSV61826624, COSV61827751; called by muse, mutect2, varscan2
- OPA1 | c.2210C>T p.S737F (on ENST00000361510 / NM_130837.3; = p.S682F on NM_015560.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV62478674; called by muse, mutect2, varscan2
- OPRM1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs201516315, COSV57679855, COSV57679871; called by muse, mutect2, varscan2
- OR10G4 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100304853; called by muse, mutect2, varscan2
- OR13H1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 178/192 reads (93%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as rs766468103, COSV58547498; called by muse, mutect2, varscan2
- OR14A16 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV62926959; called by muse, mutect2, varscan2
- OR1L1 | c.272G>A p.G91E (on ENST00000373686; = p.G41E on NM_001005236.3) | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390819796, COSV58935923; called by muse, mutect2, varscan2
- OR2AG1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776088768; called by muse, mutect2, varscan2
- OR2B11 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59510657; called by muse, mutect2, varscan2
- OR2M4 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1192709932, COSV60708803, COSV60709747; called by muse, mutect2, varscan2
- OR4C3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100168090, COSV60587749; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 141/346 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR4K1 | c.101T>A p.V34D | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV53460992; called by muse, mutect2, varscan2
- OR4X1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60722348, COSV60724098; called by muse, mutect2, varscan2
- OR51S1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV59059112; called by muse, mutect2, varscan2
- OR52A1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); catalogued as COSV100200448, COSV61092329; called by muse, mutect2, varscan2
- OR56B1 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV57723437; called by muse, mutect2, varscan2
- OR5H6 | c.867G>A p.M289I (on ENST00000642105; = p.M273I on NM_001005479.2) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs761413473, COSV67351719; called by muse, mutect2, varscan2
- OR5I1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56886245; called by muse, mutect2, varscan2
- OR6C2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 76/95 reads (80%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV59516385; called by muse, mutect2, varscan2
- OR6N2 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV59411174, COSV59411258, COSV59412030; called by muse, mutect2, varscan2
- OR8D4 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV58429930; called by muse, mutect2
- OSBPL9 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61872080; called by muse, mutect2, varscan2
- OTOF | c.3014C>T p.P1005L (on ENST00000272371 / NM_194248.3; = p.P258L on NM_004802.4) | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55508394; called by muse, mutect2, varscan2
- OXER1 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); catalogued as rs761848018, COSV54310143; called by muse, mutect2, varscan2
- P2RX1 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56654528; called by muse, mutect2, varscan2
- P2RY14 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1286694741, COSV56385405; called by muse, mutect2, varscan2
- PAMR1 | c.1375G>A p.G459R (on ENST00000619888 / NM_001001991.3; = p.G476R on NM_015430.4) | Missense Mutation (SNP) | VAF 117/268 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.227); catalogued as COSV53513899; called by muse, mutect2, varscan2
- PAPPA | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); catalogued as COSV60286951; called by muse, mutect2, varscan2
- PAPPA | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60286958; called by muse, mutect2, varscan2
- PAPPA2 | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772178636, COSV62778438; called by muse, mutect2, varscan2
- PAPPA2 | c.4097C>T p.S1366L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773829570, COSV62801601; called by muse, mutect2, varscan2
- PARM1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV56655813; called by muse, mutect2
- PCDH18 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61268410, COSV61268565; called by muse, mutect2, varscan2
- PCDHA5 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 218/263 reads (83%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV65353977; called by muse, mutect2, varscan2
- PCDHAC1 | c.2263C>T p.L755F | Missense Mutation (SNP) | VAF 83/98 reads (85%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53845867, COSV53857557; called by muse, mutect2, varscan2
- PCDHB7 | c.1354A>G p.T452A | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.314); catalogued as COSV50786276; called by muse, mutect2, varscan2
- PCDHGA5 | c.2338C>T p.L780F | Missense Mutation (SNP) | VAF 228/272 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs267600455, COSV53978925; called by muse, mutect2, varscan2
- PCDHGA6 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 74/82 reads (90%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.034); catalogued as COSV53901073, COSV53915353; called by muse, mutect2, varscan2
- PCDHGB3 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 56/60 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV53919462; called by muse, mutect2, varscan2
- PCLO | c.10844C>T p.S3615F | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61646591; called by muse, varscan2
- PCLO | c.10828G>A p.V3610I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61646604; called by muse, varscan2
- PCLO | c.8095C>T p.P2699S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs551639501, COSV100437801, COSV61624916; called by muse, mutect2, varscan2
- PCLO | c.5986T>C p.S1996P | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61646627; called by muse, mutect2, varscan2
- PCSK1 | c.1653G>A p.W551* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | catalogued as COSV60736273; called by muse, mutect2, varscan2
- PDYN | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV54102426; called by muse, mutect2, varscan2
- PEAK1 | c.3758C>T p.S1253F | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56933809; called by muse, mutect2, varscan2
- PEAR1 | c.2838G>A p.M946I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52771474; called by muse, mutect2, varscan2
- PEG10 | c.637C>T p.H213Y (on ENST00000482108 / NM_001040152.2; = p.H247Y on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV71788414; called by muse, mutect2, varscan2
- PEG3 | c.3834A>C p.E1278D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.81); catalogued as COSV55638620; called by muse, mutect2, varscan2
- PEX5L | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs374485695; called by muse, mutect2, varscan2
- PGAM2 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 51/182 reads (28%) | catalogued as COSV51978875; called by muse, mutect2, varscan2
- PGK2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs1043925533, COSV59164495; called by muse, mutect2, varscan2
- PGLYRP4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as COSV100668414, COSV62835687; called by muse, mutect2, varscan2
- PHC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as rs1372570634, COSV70418274; called by muse, mutect2, varscan2
- PHF10 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59323079, COSV59323815; called by muse, mutect2, varscan2
- PIK3C2G | c.2711G>A p.R904K (on ENST00000676171; = p.R863K on NM_004570.5) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV56816942; called by muse, mutect2, varscan2
- PIK3CD | c.2795T>G p.F932C | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63127391; called by muse, mutect2, varscan2
- PIK3CG | c.2971T>G p.F991V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63250083; called by muse, mutect2, varscan2
- PIK3R6 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61004110; called by muse, mutect2, varscan2
- PIKFYVE | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.15); catalogued as COSV52244272; called by muse, mutect2, varscan2
- PIP4P2 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV53439360, COSV99575532; called by muse, mutect2, varscan2
- PIP5K1C | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as rs1304528623, COSV58953848; called by muse, mutect2, varscan2
- PITPNC1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV55452909; called by muse, mutect2, varscan2
- PKD1 | c.8425C>T p.P2809S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV51919796; called by muse, mutect2, varscan2
- PKHD1 | c.4697C>T p.S1566F | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs777910113, COSV61883973; called by muse, mutect2, varscan2
- PKHD1L1 | c.8423G>A p.G2808E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV65746760; called by muse, mutect2, varscan2
- PKP2 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV50735598; called by muse, mutect2, varscan2
- PLAT | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 98/368 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV54276674; called by muse, mutect2, varscan2
- PLCB2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs765646154, COSV53035207; called by muse, mutect2, varscan2
- PLCL1 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs766267203, COSV70821783, COSV70822812; called by muse, mutect2, varscan2
- PLEC | c.631C>T p.H211Y (on ENST00000322810 / NM_201380.4; = p.H101Y on NM_000445.5) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59656207; called by muse, varscan2
- PLEKHA6 | c.2860A>G p.I954V | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV55336010; called by muse, mutect2, varscan2
- PLEKHG6 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV50603882; called by muse, mutect2, varscan2
- PLEKHM3 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.625); catalogued as COSV70136462; called by muse, mutect2, varscan2
- PLEKHN1 | c.1648G>A p.V550M (on ENST00000379409; = p.V498M on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as COSV58022564; called by muse, mutect2, varscan2
- PLG | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV51984901; called by muse, mutect2, varscan2
- PLPPR5 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 61/96 reads (64%) | catalogued as rs756448637, COSV54175166; called by muse, mutect2, varscan2
- PLXDC2 | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65905816; called by muse, mutect2, varscan2
- PLXNA3 | c.3161C>T p.P1054L | Missense Mutation (SNP) | VAF 143/164 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860278; called by muse, mutect2, varscan2
- PLXNB3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 70/76 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV62798956; called by muse, mutect2, varscan2
- POF1B | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53136441; called by muse, mutect2
- POFUT2 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV57959814; called by muse, mutect2, varscan2
- PPFIA1 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54137119; called by muse, mutect2, varscan2
- PPFIA1 | c.3361G>A p.G1121R | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1292048563; called by muse, mutect2, varscan2
- PPP1R12C | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 180/414 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.08); catalogued as rs1385123728, COSV54737992, COSV54738431; called by muse, mutect2, varscan2
- PRC1 | c.823-2A>C p.X275_splice | Splice Site (SNP) | VAF 50/127 reads (39%) | catalogued as COSV62695914; called by muse, mutect2, varscan2
- PRKDC | c.4151T>A p.F1384Y | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58057013; called by muse, mutect2, varscan2
- PRLR | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs963122771, COSV51497422; called by muse, mutect2, varscan2
- PRSS1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs765342413, COSV61194394; called by muse, mutect2, varscan2
- PRUNE2 | c.6055C>T p.P2019S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV65043499; called by muse, mutect2, varscan2
- PSG3 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV59505361; called by muse, mutect2, varscan2
- PSG4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 218/506 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as rs1310243477, COSV54937305; called by muse, mutect2, varscan2
- PSG6 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 117/270 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.578); catalogued as COSV51834855; called by muse, mutect2, varscan2
- PSG6 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 124/292 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs370759098, COSV51834884; called by muse, mutect2, varscan2
- PSMC3 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54081648; called by muse, mutect2, varscan2
- PSME4 | c.5064G>A p.W1688* | Nonsense Mutation (SNP) | VAF 53/126 reads (42%) | catalogued as COSV66363684, COSV66366067; called by muse, mutect2, varscan2
- PTK7 | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 57/126 reads (45%) | catalogued as COSV57849691; called by muse, mutect2, varscan2
- PTPN23 | c.4465C>T p.L1489F | Missense Mutation (SNP) | VAF 126/267 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55545905; called by muse, mutect2, varscan2
- PTPRG | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs185135949, COSV55649075; called by muse, mutect2, varscan2
- PUM1 | c.2784G>T p.L928F | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV57087935; called by muse, mutect2, varscan2
- PWWP3A | c.662A>G p.N221S (on ENST00000627377; = p.N220S on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as COSV60903144; called by muse, mutect2, varscan2
- RALGAPA2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777796459, COSV52502373; called by muse, mutect2, varscan2
- RANBP2 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs748226800, COSV51703574; called by muse, mutect2, varscan2
- RANBP2 | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV51703591; called by muse, mutect2, varscan2
- RASA1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV57193662; called by muse, mutect2, varscan2
- RASA1 | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57197977; called by muse, mutect2, varscan2
- RASGRP3 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV67823075; called by muse, mutect2, varscan2
- RBMS3 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV56153814; called by muse, mutect2, varscan2
- RBPJL | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.516); catalogued as COSV59214386; called by muse, mutect2, varscan2
- RC3H1 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 159/331 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.129); catalogued as COSV51204994, COSV51208179; called by muse, mutect2, varscan2
- RCVRN | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1483251494, COSV56841854; called by muse, mutect2, varscan2
- RGL4 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 71/117 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1455603628, COSV51944581, COSV99318818; called by muse, mutect2, varscan2
- RHBDF2 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as COSV57421302; called by muse, mutect2, varscan2
- RIF1 | c.6436C>T p.Q2146* | Nonsense Mutation (SNP) | VAF 41/92 reads (45%) | catalogued as COSV54619575; called by muse, mutect2, varscan2
- RIMBP2 | c.1682G>A p.G561D | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV55477156; called by muse, mutect2, varscan2
- RIOK2 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.401); catalogued as COSV51613627; called by muse, mutect2, varscan2
- RNF133 | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57371779; called by muse, mutect2
- RNF168 | c.1696T>C p.F566L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV58838613; called by muse, mutect2, varscan2
- RNF17 | c.4228C>T p.P1410S | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs774147952, COSV55044225; called by muse, mutect2, varscan2
- RNF32 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV58730817; called by muse, mutect2, varscan2
- RNF39 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV99748626; called by muse, mutect2
- RP1 | c.6460G>A p.E2154K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55120418; called by muse, mutect2, varscan2
- RP1L1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs759011494, COSV66751378; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPGRIP1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV52852194; called by muse, mutect2, varscan2
- RTN4R | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV50381792; called by muse, mutect2, varscan2
- RUNDC3B | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1235770568, COSV56694702; called by muse, mutect2, varscan2
- RXFP2 | c.1660G>C p.V554L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs755745145, COSV53637523, COSV99036474; called by muse, mutect2, varscan2
- RYR1 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV62102280; called by muse, mutect2, varscan2
- RYR2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV63695628; called by muse, mutect2, varscan2
- RYR3 | c.11570C>T p.S3857F (on ENST00000389232; = p.S3858F on NM_001036.6) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66790618; called by muse, mutect2, varscan2
- SALL4 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1325164721, COSV53851950, COSV53853873, COSV99409810; called by muse, mutect2, varscan2
- SCFD2 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 110/233 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV66373978; called by muse, mutect2, varscan2
- SCML2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 63/67 reads (94%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1179761295, COSV52622868, COSV52624106; called by muse, mutect2, varscan2
- SCN10A | c.5386G>A p.D1796N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV71862009; called by muse, varscan2
- SCN10A | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs267599796, COSV71860696; called by muse, varscan2
- SCN10A | c.3787C>T p.R1263* | Nonsense Mutation (SNP) | VAF 66/152 reads (43%) | catalogued as rs868612986, COSV71862011; called by muse, mutect2, varscan2
- SCN3A | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | catalogued as rs1553535431, COSV51801086; called by muse, mutect2, varscan2
- SCNN1G | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267604467, COSV55599920; called by muse, mutect2, varscan2
- SCUBE1 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV62613883; called by muse, mutect2, varscan2
- SDK2 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as rs748601515, COSV66181801; called by muse, mutect2, varscan2
- SEC13 | c.661G>A p.A221T (on ENST00000350697 / NM_183352.3; = p.A224T on NM_030673.4) | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61601633; called by muse, mutect2, varscan2
- SEC23B | c.198T>A p.C66* | Nonsense Mutation (SNP) | VAF 117/266 reads (44%) | catalogued as COSV52721692; called by muse, mutect2, varscan2
- SEC24B | c.3187T>G p.S1063A | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV54502224; called by muse, mutect2, varscan2
- SELENOI | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53145463; called by muse, mutect2, varscan2
- SERPINB1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs201796977, COSV66313808; called by muse, mutect2, varscan2
- SERPINB10 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53074006; called by muse, mutect2, varscan2
- SERPINB2 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.557); catalogued as COSV53073997; called by muse, mutect2, varscan2
- SETDB1 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54986820; called by muse, varscan2
- SETDB1 | c.1727A>G p.H576R | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54985816, COSV54986867; called by muse, varscan2
- SEZ6 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as rs376504969; called by muse, mutect2, varscan2
- SF3B2 | c.426_428del p.E145del | In Frame Del (DEL) | VAF 14/95 reads (15%) | catalogued as rs1339714892; called by mutect2, pindel, varscan2
- SGSM2 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52155745, COSV52159414; called by muse, mutect2, varscan2
- SH3D19 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 249/747 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58791673; called by muse, mutect2, varscan2
- SH3RF2 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 121/137 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV63039915; called by muse, mutect2, varscan2
- SHOX2 | c.582A>T p.K194N (on ENST00000441443 / NM_006884.3; = p.K218N on NM_003030.4) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67464170; called by muse, mutect2, varscan2
- SHROOM3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs746483211, COSV56033263, COSV56039198; called by muse, mutect2, varscan2
- SI | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs769345842, COSV52286715; called by muse, mutect2, varscan2
- SIGLEC14 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV55778223; called by muse, mutect2, varscan2
- SLC15A2 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs368822521; called by muse, mutect2, varscan2
- SLC17A1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55080076, COSV99765680; called by muse, mutect2, varscan2
- SLC18A1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs574480936, COSV52349192; called by muse, mutect2, varscan2
- SLC22A14 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV56198287; called by muse, mutect2, varscan2
- SLC22A16 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.185); catalogued as rs781207718, COSV57931432; called by muse, mutect2, varscan2
- SLC25A2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV53404323; called by muse, mutect2
- SLC25A2 | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1554296016, COSV53404334; called by muse, mutect2
- SLC25A24 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 102/169 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV51448713; called by muse, mutect2, varscan2
- SLC25A37 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328077616, COSV51564866; called by muse, mutect2, varscan2
- SLC26A5 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 84/153 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59701896, COSV59703331; called by muse, mutect2, varscan2
- SLC26A9 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV61604014; called by muse, mutect2, varscan2
- SLC27A6 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1315273250, COSV52482732; called by muse, mutect2, varscan2
- SLC30A9 | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52557276; called by muse, mutect2, varscan2
- SLC34A2 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.005); catalogued as rs747570357, COSV65942124; called by muse, mutect2, varscan2
- SLC5A12 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54819134, COSV54822852; called by muse, mutect2, varscan2
- SLC6A4 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55568066, COSV55569668; called by muse, mutect2, varscan2
- SLC8A3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV63523098; called by muse, mutect2, varscan2
- SLC9A1 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 83/285 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56054650; called by muse, mutect2, varscan2
- SLITRK1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV65676579; called by muse, mutect2, varscan2
- SMARCB1 | c.482A>G p.N161S (on ENST00000263121; = p.N207S on NM_003073.5) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as rs763872301, COSV54098741; called by muse, mutect2, varscan2
- SMC1B | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.36); PolyPhen benign (0.44); catalogued as rs756907087, COSV62530349; called by muse, mutect2, varscan2
- SMC6 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV61176040; called by muse, mutect2, varscan2
- SMOC2 | c.1138C>T p.R380C (on ENST00000356284 / NM_001166412.2; = p.R391C on NM_022138.3) | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148539759; called by muse, mutect2, varscan2
- SNAP47 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs143073539, COSV100247811; called by muse, mutect2, varscan2
- SNAP91 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52122796; called by muse, mutect2, varscan2
- SORCS2 | c.2483A>G p.Y828C | Missense Mutation (SNP) | VAF 193/485 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61175113; called by muse, mutect2, varscan2
- SORL1 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV52757273; called by muse, mutect2, varscan2
- SORL1 | c.3893G>A p.G1298E | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52757283, COSV52764299; called by muse, mutect2, varscan2
- SPAG5 | c.1978A>G p.S660G | Missense Mutation (SNP) | VAF 125/211 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1466121585, COSV58802723; called by muse, mutect2, varscan2
- SPAG9 | c.1429C>T p.R477W (on ENST00000262013 / NM_001130528.3; = p.R463W on NM_003971.6) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772023935, COSV56235737; called by muse, mutect2, varscan2
- SPHKAP | c.5008G>A p.D1670N (on ENST00000392056 / NM_001142644.2; = p.D1641N on NM_030623.3) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60884736; called by muse, mutect2, varscan2
- SPHKAP | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 112/232 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60884498; called by muse, mutect2, varscan2
- SPIC | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 94/116 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746088939, COSV54690815; called by muse, mutect2, varscan2
- SPO11 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61996167; called by muse, mutect2, varscan2
- SRCAP | c.8645C>T p.S2882L | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs770457886, COSV52675823; called by muse, mutect2, varscan2
- SRSF5 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs142745234; called by muse, mutect2, varscan2
- SSTR2 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV59535463; called by muse, mutect2, varscan2
- ST14 | c.2309T>C p.V770A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV53834542; called by muse, mutect2
- ST6GAL2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 98/255 reads (38%) | PolyPhen probably damaging (0.932); catalogued as rs138821621; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | PolyPhen possibly damaging (0.474); catalogued as COSV60326906; called by muse, mutect2, varscan2
- ST8SIA5 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 75/248 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV59333251; called by muse, mutect2, varscan2
- STAB1 | c.6649G>A p.G2217S | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs552936256; called by muse, mutect2, varscan2
- STK31 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV63454655; called by muse, mutect2, varscan2
- STK31 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV63455699; called by muse, mutect2, varscan2
- STOML3 | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV65511201; called by muse, mutect2
- STX19 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57399462; called by muse, mutect2, varscan2
- STYXL2 | c.2258G>A p.S753N | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54807023, COSV99609666; called by muse, mutect2, varscan2
- SULF2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1307958275, COSV63417768; called by muse, mutect2, varscan2
- SULT1C2 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV52265688; called by muse, mutect2, varscan2
- SULT1C3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs866697546, COSV61252236; called by muse, mutect2, varscan2
- SVEP1 | c.7163C>T p.S2388F | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.622); catalogued as COSV52840949; called by muse, mutect2, varscan2
- SYNE1 | c.772C>T p.P258S (on ENST00000367255 / NM_182961.4; = p.P265S on NM_033071.3) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs762357598, COSV55025418; called by muse, mutect2, varscan2
- SYTL5 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52902798; called by muse, mutect2, varscan2
- SYVN1 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53695447; called by muse, mutect2, varscan2
- TACC2 | c.4783C>T p.P1595S | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs375588375; called by muse, mutect2, varscan2
- TACC2 | c.6448G>A p.V2150M (on ENST00000334433; = p.V228M on NM_006997.4) | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751241062, COSV53284064; called by muse, mutect2, varscan2
- TANC1 | c.4721C>T p.P1574L | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1455665212; called by muse, mutect2, varscan2
- TAS2R42 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV62084571; called by muse, mutect2, varscan2
- TBCB | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 419/949 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs1158190857, COSV55692009; called by muse, mutect2, varscan2
- TBX2 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs767959344, COSV53599830; called by muse, mutect2, varscan2
- TEP1 | c.4792C>T p.L1598F | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52995305; called by muse, mutect2, varscan2
- TGM7 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV71772919; called by muse, mutect2, varscan2
- THAP9 | c.2246T>C p.I749T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56356919; called by muse, mutect2, varscan2
- THRAP3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs777332431, COSV63568643; called by muse, mutect2, varscan2
- THSD4 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 165/334 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV55975134; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TICRR | c.5635G>T p.E1879* | Nonsense Mutation (SNP) | VAF 262/550 reads (48%) | catalogued as COSV51543322; called by muse, mutect2, varscan2
- TM7SF3 | c.868+2T>G p.X290_splice | Splice Site (SNP) | VAF 34/154 reads (22%) | catalogued as COSV58003013; called by muse, mutect2, varscan2
- TMCC2 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV58001847; called by muse, mutect2, varscan2
- TMEM132B | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV100169269, COSV54758862; called by muse, mutect2, varscan2
- TMEM144 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 87/302 reads (29%) | catalogued as rs1209028272, COSV56701762; called by muse, mutect2, varscan2
- TMEM196 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs753809570, COSV101337537, COSV68255396; called by muse, mutect2, varscan2
- TMEM63B | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52480483; called by muse, mutect2
- TMOD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774263793, COSV57944721; called by muse, mutect2, varscan2
- TMPRSS11A | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs757090282, COSV58357045; called by muse, mutect2
- TMPRSS2 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV59824433; called by muse, mutect2, varscan2
- TNR | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54874438; called by muse, mutect2, varscan2
- TNRC18 | c.5459C>T p.S1820L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1403934106, COSV68165185; called by muse, mutect2, varscan2
- TNXB | c.11068C>A p.P3690T (on ENST00000647633; = p.P3443T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs181032487; called by muse, mutect2, varscan2
- TNXB | c.11067T>A p.A3689= (on ENST00000647633; = p.A3442= on NM_019105.8 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 23/48 reads (48%) | catalogued as rs184661158; called by muse, mutect2, varscan2
- TNXB | c.6685C>T p.P2229S (on ENST00000647633; = p.P1982S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV64482464; called by muse, mutect2, varscan2
- TOP2A | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 116/381 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV70733044; called by muse, mutect2, varscan2
- TOX2 | c.1278G>A p.M426I (on ENST00000358131 / NM_001098798.2; = p.M402I on NM_032883.3) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as rs1238068624, COSV100364534, COSV57889415; called by muse, mutect2, varscan2
- TP53 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 436/735 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as CD114001, COSV52987957, COSV53821134; called by muse, mutect2, varscan2
- TP53BP1 | c.878A>T p.K293M | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV55504130; called by muse, mutect2, varscan2
- TP63 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53211314; called by muse, mutect2, varscan2
- TPP2 | c.3063T>A p.F1021L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV65751468, COSV65753502; called by muse, mutect2, varscan2
- TPRG1 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV61466452; called by mutect2, varscan2
- TPT1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.056); catalogued as COSV58538987; called by muse, mutect2, varscan2
- TRANK1 | c.8636G>A p.R2879Q | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs779444903, COSV57155210; called by muse, mutect2, varscan2
- TRDV1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs375714873; called by muse, mutect2, varscan2
- TRIM42 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); catalogued as COSV53884492; called by muse, mutect2, varscan2
- TRIM44 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV54985561; called by muse, mutect2, varscan2
- TRIM63 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65328835; called by muse, mutect2, varscan2
- TRIM67 | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100792188, COSV64159270; called by muse, mutect2, varscan2
- TRIO | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs772378892, COSV60077913; called by muse, mutect2, varscan2
- TRPC4 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 64/143 reads (45%) | catalogued as rs1451217859, COSV59006144; called by muse, mutect2, varscan2
- TRPC4 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV59006160, COSV59013685; called by muse, mutect2, varscan2
- TRPM4 | c.2614C>T p.L872F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780687748, COSV53261452; called by muse, mutect2, varscan2
- TRPS1 | c.572C>T p.S191L (on ENST00000220888 / NM_001330599.2; = p.S204L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV55249400; called by muse, mutect2, varscan2
- TRRAP | c.10775C>T p.S3592F (on ENST00000359863 / NM_001244580.1; = p.S3563F on NM_003496.3) | Missense Mutation (SNP) | VAF 100/395 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV62815812; called by muse, mutect2, varscan2
- TTBK1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV52493527, COSV99443547; called by muse, mutect2, varscan2
- TTC16 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64777584; called by muse, mutect2, varscan2
- TTC21A | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV57186610, COSV57187887; called by muse, mutect2, varscan2
- TTI1 | c.2822G>A p.G941D | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1191541809, COSV65060545; called by muse, mutect2, varscan2
- TTK | c.2434G>A p.V812I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773730783, COSV57884873; called by muse, mutect2, varscan2
- TTN | c.101059G>A p.E33687K (on ENST00000591111; = p.E26263K on NM_003319.4) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | PolyPhen benign (0.337); catalogued as COSV60168508; called by muse, mutect2, varscan2
- TTN | c.51637G>A p.E17213K (on ENST00000591111; = p.E9789K on NM_003319.4) | Missense Mutation (SNP) | VAF 90/208 reads (43%) | PolyPhen possibly damaging (0.562); catalogued as COSV59933833; called by muse, mutect2, varscan2
- TTN | c.28654G>A p.E9552K (on ENST00000591111; = p.E8625K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/118 reads (45%) | PolyPhen probably damaging (0.994); catalogued as COSV59895218; called by muse, mutect2, varscan2
- TTN | c.22733C>T p.P7578L (on ENST00000591111; = p.P6651L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | PolyPhen benign (0.015); catalogued as COSV60168543; called by muse, mutect2, varscan2
- TTN | c.18712G>A p.V6238M (on ENST00000591111; = p.V5311M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | PolyPhen possibly damaging (0.839); catalogued as rs753901455, COSV60168547; called by muse, mutect2, varscan2
- TTN | c.16351G>A p.D5451N (on ENST00000591111; = p.D4524N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | PolyPhen benign (0.052); catalogued as rs576904726, COSV59905599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6853G>A p.E2285K (on ENST00000591111; = p.E2239K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | PolyPhen probably damaging (0.994); catalogued as COSV60168593; called by muse, mutect2, varscan2
- TTN | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | PolyPhen possibly damaging (0.533); catalogued as COSV100633904, COSV60168644; called by muse, mutect2, varscan2
- TUBB8 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs1554738810, COSV59116542; called by muse, mutect2, varscan2
- TULP2 | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55478879; called by muse, mutect2, varscan2
- TXLNB | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.314); catalogued as COSV64444667; called by muse, mutect2, varscan2
- UBAP1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 66/73 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV52659919; called by muse, mutect2, varscan2
- UBR5 | c.8249C>T p.P2750L | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55292274; called by muse, mutect2, varscan2
- UGT2B10 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV55321100, COSV55321680; called by muse, mutect2, varscan2
- UGT2B4 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); catalogued as COSV59318327; called by muse, mutect2, varscan2
- UNC13C | c.5867C>T p.S1956F | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs779696884, COSV52893388; called by muse, mutect2, varscan2
- UNC5D | c.2620G>A p.D874N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54809180; called by muse, mutect2, varscan2
- UPB1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58114378; called by muse, mutect2, varscan2
- USF3 | c.2642C>T p.S881L | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs760900951, COSV57071598; called by muse, mutect2, varscan2
- USF3 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57074711; called by muse, mutect2, varscan2
- USH1G | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 113/249 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as rs1316299165, COSV58881627; called by muse, mutect2, varscan2
- USP25 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV53486474; called by muse, mutect2, varscan2
- USP33 | c.2230C>T p.R744* | Nonsense Mutation (SNP) | VAF 57/86 reads (66%) | catalogued as COSV62469883; called by muse, mutect2, varscan2
- USP45 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57329438; called by muse, mutect2, varscan2
- VCAN | c.9250G>A p.A3084T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1311831031, COSV54109178; called by muse, mutect2, varscan2
- VCL | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489339580, COSV53011478; called by muse, mutect2, varscan2
- VGLL4 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as COSV56078850; called by muse, mutect2, varscan2
- VIRMA | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278500361, COSV52582824; called by muse, mutect2, varscan2
- VIT | c.1234G>A p.E412K (on ENST00000389975 / NM_001177969.1; = p.E427K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64897629; called by muse, mutect2, varscan2
- VNN2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs775545409, COSV58472700; called by muse, mutect2, varscan2
- VPS8 | c.3376C>T p.L1126F (on ENST00000625842 / NM_001349294.1; = p.L1124F on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV54989778; called by muse, mutect2, varscan2
- VWA3A | c.2566A>G p.K856E | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV55392516; called by muse, mutect2, varscan2
- WARS2 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 105/153 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as rs762869916, COSV52480032; called by muse, mutect2, varscan2
- WDR33 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV59251775; called by muse, mutect2, varscan2
- WDR49 | c.820G>A p.E274K (on ENST00000308378 / NM_001366158.1; = p.E615K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); catalogued as COSV57711696; called by muse, mutect2, varscan2
- WDR6 | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 155/340 reads (46%) | catalogued as COSV58245694; called by muse, mutect2, varscan2
- WNT10A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs749324327, COSV51463005; called by muse, mutect2, varscan2
- XPNPEP3 | c.117G>C p.R39S | Missense Mutation (SNP) | VAF 118/218 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV64027455; called by muse, mutect2, varscan2
- XRN1 | c.4999C>T p.Q1667* | Nonsense Mutation (SNP) | VAF 57/85 reads (67%) | catalogued as rs78926178, COSV53814218; called by muse, mutect2, varscan2
- YEATS2 | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59368208; called by muse, mutect2, varscan2
- YEATS2 | c.2306C>A p.S769* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV59368223; called by muse, mutect2, varscan2
- YIPF2 | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53404303; called by muse, mutect2, varscan2
- YPEL3 | c.190G>A p.E64K (on ENST00000398838 / NM_001145524.2; = p.E102K on NM_031477.5) | Missense Mutation (SNP) | VAF 125/144 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV54222412; called by muse, mutect2, varscan2
- ZAN | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.234); catalogued as COSV61811235; called by muse, mutect2
641 further variants in this file (180 protein-altering or splice-affecting, 425 silent, 36 other) are not listed here.
